Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3692, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3692-01A (Primary Tumor).

Diagnosis:

Colon resection material includes a mucinous, moderately differentiated adenocarcinoma of the colorectal type, showing circular growth and measuring a maximum of 5 cm in diameter with widespread infiltration of the pericolic fatty tissue and with five regional lymph node metastases. Tumor-free colon resection margins. Close to one resection margin a clip-marked mucosal defect with florid inflammatory lesions and fibrin insudation of the submucosa, evidently in status post excision of a polyp or a neoplasia (see previous finding

Tumor stage: pT3 pN2 (5/30) M1 (clinically liver metastases); G2, L0, V0, clinically R2

Source: NCI Genomic Data Commons file a7419cea-f700-4ed0-bd26-dbc96140f3d1 (TCGA-AA-3692.F899F217-0D34-4477-8AE3-80640AE34889.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).